Gene-level copy-number profile of tumor specimen C3L-05477-01 from CPTAC case C3L-05477, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 67.8 years (24,756 days).
Specimen C3L-05477-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e88b4dad-70ad-4b23-824f-070869d6c168.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-05477-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,727 have no estimate.
https://portal.gdc.cancer.gov/files/3d34f8e8-58e3-4c7a-acf9-e13ed73a6039

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 533; copy number 1: 616; copy number 2: 2,636; copy number 3: 14,184; copy number 4: 21,232; copy number 5: 9,001; copy number 6: 4,429; copy number 7: 1,662; copy number 8: 1,203; copy number 9: 1,000; copy number 10: 1,695; copy number 11: 510; copy number 12: 138; copy number 13: 11; copy number 34: 46.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:4,117,925–4,150,421, 3 genes: AC116562.1, OR7E103P, UNC93B4.
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr10:79,703,227–79,714,681, 1 gene (within-gene range 0–2): NUTM2B.
- chr22:18,340,145–18,391,105, 3 genes: GGTLC5P, FAM230J, AC011718.1.
- chr22:18,715,815–18,843,399, 5 genes: PPP1R26P4, FAM230E, GGT3P, AC008132.2, E2F6P1.
- chr22:18,906,028–18,947,732, 3 genes (within-gene range 0–3): DGCR6, AC007326.4, PRODH.
- chr22:38,952,741–38,992,804, 2 genes (within-gene range 0–3): APOBEC3A, APOBEC3B.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,400 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:167,065,831–167,734,939, 7 genes, copy number 34: PPIAP74, ZBBX, LINC01327, SERPINI2, WDR49, PDCD10, HMGN1P8.
- chr3:168,858,659–170,418,615, 39 genes, copy number 34: RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997, MECOM, MECOM-AS1, RPL22P1, AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3, PHC3, RNU6-315P, PRKCI, Y_RNA, AC073288.1, SKIL, AC073288.2.
- chr5:58,198–45,895,970, 679 genes, copy number 9–12 (broad region; genes not listed).
- chr7:37,032–56,497,285, 962 genes, copy number 9–11 (broad region; genes not listed).
- chr8:79,259,402–81,924,348, 68 genes, copy number 9 (broad region; genes not listed).
- chr8:82,098,451–82,292,379, 2 genes, copy number 9: LINC02839, HNRNPA1P4.
- chr8:93,213,302–93,700,433, 1 gene, copy number 9 (within-gene range 8–9): LINC00535.
- chr8:93,259,667–96,611,790, 75 genes, copy number 9 (broad region; genes not listed).
- chr8:97,241,742–104,256,094, 162 genes, copy number 9 (broad region; genes not listed).
- chr8:115,950,511–128,187,101, 182 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr10:35,098,006–36,089,389, 20 genes, copy number 9: AL392046.1, CREM, RNU7-77P, ATP6V1G1P4, AL117336.1, LINC02634, RNU6-794P, CCNY, RNU6-1167P, AL117336.2, AL603824.1, AL121749.1, GJD4, FZD8, AL121749.2, MIR4683, RPL7P37, PCAT5, LINC02630, AL355300.1.
- chr11:112,967–186,136, 5 genes, copy number 11 (within-gene range 6–11): AC069287.1, CICP23, LINC01001, AC069287.3, RNU6-447P.
- chr13:23,134,174–28,138,193, 119 genes, copy number 12 (broad region; genes not listed).
- chr13:73,036,401–74,565,445, 21 genes, copy number 9: PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392, KLF12, AL138713.1, AL159972.1, LINC00402, AL353660.1, RNY1P5, RPL21P108, AL355390.1, LINC00381, AL355390.2, LINC00347.
- chr14:18,333,726–18,650,966, 17 genes, copy number 11: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12, CR383656.8, CR383656.11.
- chr14:19,954,490–20,723,127, 56 genes, copy number 9–10: OR4K16P, OR4K15, OR4Q2, OR4K14, OR4K13, OR4U1P, OR4L1, RNA5SP380, OR4T1P, OR4K17, OR4N5, PSMB7P1, GTF2IP22, OR11G1P, OR11G2, OR11H5P, OR11H6, OR11H7, OR11H4, TTC5, AL356019.2, AL356019.1, CCNB1IP1, AL355075.6, SNORA79B, SNORD126, AL355075.4, RPPH1, PARP2, AL355075.1, TEP1, RNA5SP382, KLHL33, AL355075.5, OSGEP, AL355075.2, APEX1, PIP4P1, PNP, AL355075.3, RNASE10, PTCD2P1, SETP1, RNASE9, AL163195.3, RNASE11, AL163195.2, RNASE12, AL163195.1, OR6S1, Y_RNA, ANG, RNASE4, AL163636.1, EGILA, RANBP20P.
- chr20:21,947,647–22,685,344, 11 genes, copy number 13: AL109807.1, LINC01432, AL035258.1, LINC01427, AL049737.1, AL121912.1, AL133464.1, LINC00261, FOXA2, LNCNEF, LINC01747.
- chr20:22,885,670–64,327,972, 974 genes, copy number 9–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 616. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
